Somatic mutation profile of tumor specimen TCGA-A3-A8OV-01A (aliquot TCGA-A3-A8OV-01A-11D-A36X-10) from TCGA case TCGA-A3-A8OV, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.4 years (27,526 days).
Specimen TCGA-A3-A8OV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3eadbc07-5a3a-4c84-a3b0-b244ab8aff85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-A8OV-10A (Blood Derived Normal), aliquot TCGA-A3-A8OV-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1459c4db-6f0a-45f5-869f-bf65c2645aaf

The open-access MAF lists 150 somatic variants for this specimen: 117 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 32, Frame Shift Del 7, Nonsense Mutation 6, Frame Shift Ins 3, Splice Site 3, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.430G>T p.G144* | Nonsense Mutation (SNP) | VAF 87/130 reads (67%) | catalogued as rs869025650, CM058403, CM982008, COSV56544477, COSV56545017; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2882C>T p.A961V | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV99713906; called by muse, mutect2, varscan2
- ABCB1 | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV55947689; called by muse, mutect2, varscan2
- ADNP2 | c.2010G>T p.Q670H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as COSV100081116; called by muse, mutect2, varscan2
- AP1G2 | c.2062C>A p.P688T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99846069; called by muse, mutect2, varscan2
- ARHGEF2 | c.142T>A p.S48T (on ENST00000361247 / NM_001162383.2; = p.S21T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.98); catalogued as COSV100561007; called by muse, mutect2, varscan2
- ASAP2 | c.992A>C p.K331T | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV99856603; called by muse, mutect2, varscan2
- ATAD2B | c.2564T>C p.L855P | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99478239; called by muse, mutect2, varscan2
- ATG16L2 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV100352315; called by muse, mutect2, varscan2
- AXDND1 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); catalogued as rs773225654, COSV100858571; called by muse, mutect2, varscan2
- C10orf71 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as rs140186956, COSV100110518; called by muse, mutect2, varscan2
- CAMTA2 | c.700+1G>T p.X234_splice | Splice Site (SNP) | VAF 38/92 reads (41%) | catalogued as COSV100772776; called by muse, mutect2, varscan2
- CAPZA2 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100753967; called by muse, mutect2, varscan2
- CEP350 | c.2578G>C p.E860Q | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV100855053, COSV62604367; called by muse, mutect2, varscan2
- CKAP5 | c.3577A>G p.I1193V | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100371218; called by muse, mutect2, varscan2
- DGCR8 | c.1600G>T p.E534* | Nonsense Mutation (SNP) | VAF 48/145 reads (33%) | catalogued as COSV100708112; called by muse, mutect2, varscan2
- DNAH2 | c.9011C>G p.A3004G | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV101209526; called by muse, mutect2, varscan2
- DOP1A | c.3673C>T p.H1225Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.015); catalogued as COSV99382649; called by muse, varscan2
- DROSHA | c.2563G>T p.D855Y | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100757773; called by muse, mutect2
- EEPD1 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV99632811; called by muse, mutect2, varscan2
- FBXO30 | c.1781C>G p.S594C | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs1435652808, COSV99395347; called by muse, mutect2, varscan2
- FCHO2 | c.531T>G p.Y177* | Nonsense Mutation (SNP) | VAF 141/394 reads (36%) | catalogued as COSV55108350, COSV99821982; called by muse, mutect2, varscan2
- FMOD | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); catalogued as COSV100724599; called by muse, mutect2, varscan2
- GNMT | c.334+2T>C p.X112_splice | Splice Site (SNP) | VAF 21/47 reads (45%) | catalogued as COSV99769924; called by muse, mutect2, varscan2
- GRIA2 | c.1349C>A p.A450D | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV52382371; called by muse, mutect2
- HELZ2 | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100915664; called by muse, mutect2, varscan2
- HMX3 | c.166T>C p.F56L | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.009); catalogued as COSV100774162; called by muse, mutect2, varscan2
- HPS6 | c.716A>C p.K239T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); catalogued as COSV100154948; called by muse, mutect2, varscan2
- IDH3A | c.302C>A p.T101N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100210977, COSV100210983; called by muse, mutect2, varscan2
- IER2 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs768834640, COSV99460339; called by muse, mutect2, varscan2
- IMPACT | c.452T>G p.L151R | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs1266971912, COSV99408885; called by muse, mutect2, varscan2
- INPP5J | c.1145G>A p.R382K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs1223955282, COSV100459693; called by muse, mutect2, varscan2
- ITGA10 | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.241); catalogued as COSV100994997; called by muse, mutect2, varscan2
- KIAA1217 | c.56G>T p.R19I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs995045004, COSV100908227; called by muse, mutect2, varscan2
- KNTC1 | c.2509T>A p.Y837N | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100338657; called by muse, mutect2, varscan2
- LARP1B | c.294C>A p.N98K | Missense Mutation (SNP) | VAF 114/321 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99218730; called by muse, mutect2, varscan2
- LLGL1 | c.2618A>T p.Y873F | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV100375581; called by muse, mutect2, varscan2
- LLGL1 | c.2619T>G p.Y873* | Nonsense Mutation (SNP) | VAF 43/112 reads (38%) | catalogued as COSV100375582; called by muse, mutect2, varscan2
- LOXL4 | c.1343G>A p.S448N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as COSV99584102; called by muse, mutect2, varscan2
- LPO | c.1776G>A p.M592I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1299546610, COSV51857364; called by muse, mutect2, varscan2
- LRP1 | c.10859G>A p.C3620Y | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99676764; called by muse, mutect2, varscan2
- MAPK14 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100005103; called by muse, mutect2, varscan2
- MATN3 | c.279C>A p.S93R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101337464; called by muse, mutect2, varscan2
- MDH1 | c.111T>G p.I37M | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs750637827, COSV51863423, COSV99251248; called by muse, mutect2, varscan2
- METTL16 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99563698; called by muse, mutect2
- MPEG1 | c.700A>G p.S234G | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV57090597; called by muse, mutect2, varscan2
- MPP3 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101263360; called by muse, mutect2, varscan2
- NDOR1 | c.1476C>A p.D492E (on ENST00000371521 / NM_001144026.3; = p.D485E on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100789079; called by muse, mutect2, varscan2
- NME8 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.11); catalogued as COSV99553683; called by muse, mutect2, varscan2
- NRAS | c.8A>C p.E3A | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99795690; called by muse, mutect2, varscan2
- NRDC | c.150G>T p.M50I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV100703696, COSV61401602; called by muse, mutect2, varscan2
- NUDT12 | c.228T>A p.N76K | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100048299; called by muse, mutect2, varscan2
- OR10AG1 | c.670G>C p.G224R | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV100400165, COSV99044226; called by muse, mutect2, varscan2
- OR11H12 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 117/1122 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as rs1224091758, COSV101612516; called by muse, mutect2, varscan2
- P2RX2 | c.283G>C p.V95L (on ENST00000343948 / NM_170683.4; = p.R72P on NM_012226.5) | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV100267791; called by muse, varscan2
- PBDC1 | c.313T>A p.C105S | Missense Mutation (SNP) | VAF 109/151 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100972854; called by muse, mutect2, varscan2
- PBRM1 | c.1760T>C p.I587T | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV56277502; called by muse, mutect2, varscan2
- PDE6G | c.236A>G p.H79R | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV100148625; called by muse, mutect2, varscan2
- PER1 | c.2428T>A p.S810T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.444); catalogued as COSV100424777; called by muse, mutect2, varscan2
- PGAP3 | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as COSV100328662; called by muse, mutect2, varscan2
- PIK3CB | c.3141G>T p.E1047D | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100005957; called by muse, mutect2, varscan2
- PRKD3 | c.2332G>T p.E778* | Nonsense Mutation (SNP) | VAF 63/169 reads (37%) | catalogued as COSV99306555; called by muse, mutect2, varscan2
- PRSS3 | c.260C>T p.S87F (on ENST00000361005 / NM_007343.4; = p.S195F on NM_002771.3) | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100725686; called by muse, mutect2, varscan2
- PTPN2 | c.234G>C p.E78D | Missense Mutation (SNP) | VAF 103/252 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV100518690; called by muse, mutect2, varscan2
- PVR | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs758071838, COSV99495930; called by muse, mutect2, varscan2
- RAVER1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs1307252828, COSV99533032; called by muse, mutect2, varscan2
- RBM12 | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV100467918; called by muse, mutect2, varscan2
- RCC2 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV100965188; called by muse, mutect2, varscan2
- RELN | c.3052G>A p.A1018T | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100634500; called by muse, mutect2, varscan2
- RNF10 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100378879; called by muse, mutect2, varscan2
- RNF150 | c.903C>A p.H301Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100153955; called by muse, mutect2, varscan2
- ROCK1 | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775903956, COSV101296569; called by muse, mutect2, varscan2
- SAP18 | c.59T>G p.I20S (on ENST00000607003; = p.I39S on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV101229434; called by muse, mutect2, varscan2
- SBSN | c.1538G>T p.G513V (on ENST00000452271 / NM_001166034.2; = p.G170V on NM_198538.4) | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV101510097; called by muse, mutect2, varscan2
- SCAMP2 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51511150, COSV99173992; called by muse, mutect2, varscan2
- SCN9A | c.3725T>C p.L1242P (on ENST00000303354; = p.L1231P on NM_002977.3) | Missense Mutation (SNP) | VAF 130/421 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100313746; called by muse, mutect2, varscan2
- SIGMAR1 | c.563A>T p.D188V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99449579; called by muse, mutect2, varscan2
- SIGMAR1 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99449581, COSV99449617; called by muse, mutect2, varscan2
- SLC26A4 | c.2260G>T p.D754Y | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs1003248537, COSV99707347; called by muse, mutect2, varscan2
- SMG8 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56283616; called by muse, mutect2, varscan2
- SNX1 | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99976353; called by mutect2, varscan2
- SUPT16H | c.1073A>T p.E358V | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99360111; called by muse, mutect2, varscan2
- SYNE2 | c.8513A>G p.N2838S | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs777205885, COSV100648274; called by muse, mutect2, varscan2
- TAP2 | c.472T>C p.F158L | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100885293; called by muse, mutect2, varscan2
- TENM2 | c.8156G>T p.R2719I (on ENST00000518659 / NM_001122679.2; = p.R2480I on NM_001080428.3) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV101319322; called by muse, mutect2, varscan2
- TH | c.1274C>G p.S425C (on ENST00000381178 / NM_199292.3; = p.S394C on NM_000360.4) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99171158; called by muse, mutect2, varscan2
- TNN | c.258C>G p.F86L | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53424610, COSV99512656; called by muse, mutect2, varscan2
- TRIM7 | c.593A>C p.E198A | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.76); catalogued as COSV99220374; called by muse, mutect2
- TRPM6 | c.1817A>T p.Y606F | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as COSV100666777; called by muse, mutect2, varscan2
- TTC17 | c.1857G>C p.W619C | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99235767; called by muse, mutect2, varscan2
- TWNK | c.205A>C p.I69L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as CM164756, COSV99273022; called by muse, mutect2, varscan2
- USP45 | c.559T>A p.L187I | Missense Mutation (SNP) | VAF 169/510 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100328245, COSV57330106; called by muse, mutect2, varscan2
- WDR48 | c.432G>C p.W144C | Missense Mutation (SNP) | VAF 64/87 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100176829; called by muse, mutect2, varscan2
- XAB2 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60698007; called by muse, mutect2, varscan2
- XPNPEP2 | c.937C>G p.Q313E | Missense Mutation (SNP) | VAF 89/123 reads (72%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV100941523; called by muse, mutect2, varscan2
- ZBTB2 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100287780; called by muse, mutect2, varscan2
- ZFAT | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs762358171, COSV100914817; called by muse, mutect2, varscan2
- ZKSCAN4 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV101043542; called by muse, mutect2, varscan2
- ZNF146 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100757750; called by muse, mutect2, varscan2
- ZNF256 | c.783C>A p.H261Q | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56598934; called by muse, mutect2, varscan2
- ZNF414 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV99726677; called by muse, mutect2, varscan2
- ZNF414 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99726680; called by muse, mutect2, varscan2
- ZNF800 | c.203T>G p.I68S | Missense Mutation (SNP) | VAF 80/134 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56175333, COSV99758115; called by muse, mutect2, varscan2
- CDSN | c.552del p.G185Efs*3 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel*
- ELF1 | c.528dup p.G177Rfs*5 | Frame Shift Ins (INS) | VAF 106/345 reads (31%) | called by mutect2, pindel, varscan2
- IGHG4 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.295); called by mutect2, varscan2
- IGHG4 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- LAD1 | c.1060dup p.M354Nfs*77 | Frame Shift Ins (INS) | VAF 56/198 reads (28%) | called by mutect2, pindel, varscan2
- LRRC34 | c.822dup p.K275* (on ENST00000446859 / NM_001172779.2; = p.K243* on NM_153353.5) | Frame Shift Ins (INS) | VAF 84/220 reads (38%) | called by mutect2, varscan2
- MAPRE3 | c.450del p.K151Nfs*25 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | called by mutect2, pindel*, varscan2
- NEB | c.2671del p.T891Lfs*66 | Frame Shift Del (DEL) | VAF 135/432 reads (31%) | called by mutect2, pindel, varscan2
- POLL | c.1489_1497del p.S497_F499del | In Frame Del (DEL) | VAF 22/77 reads (29%) | called by mutect2, pindel, varscan2
- PPFIBP2 | c.879_882del p.N293Kfs*7 | Frame Shift Del (DEL) | VAF 70/210 reads (33%) | called by mutect2, pindel, varscan2
- RBM12B | c.1561_1571del p.V521* | Frame Shift Del (DEL) | VAF 36/122 reads (30%) | called by mutect2, pindel, varscan2
- SCUBE1 | c.341_349+10del p.X114_splice | Splice Site (DEL) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- TTN | c.97961del p.G32654Vfs*24 (on ENST00000591111; = p.G25230Vfs*24 on NM_003319.4) | Frame Shift Del (DEL) | VAF 42/119 reads (35%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.8348_8352del p.V2783Afs*6 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- ARHGEF37 | c.1899G>A p.E633= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV100382276; called by muse, mutect2, varscan2
- C9orf153 | c.207C>G p.G69= | Silent (SNP) | VAF 73/177 reads (41%) | catalogued as COSV100188739; called by muse, mutect2, varscan2
- CAPS | c.360G>A p.G120= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs146070385; called by muse, mutect2, varscan2
- COA4 | c.261C>T p.H87= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100142637; called by muse, mutect2, varscan2
- DAB2 | c.6T>C p.S2= | Silent (SNP) | VAF 76/202 reads (38%) | catalogued as COSV100298236; called by muse, mutect2, varscan2
- DHRS7 | c.90C>A p.G30= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as COSV99381709; called by muse, mutect2, varscan2
- ESCO1 | c.2055T>C p.I685= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as rs1442349984, COSV99332486; called by muse, mutect2, varscan2
- FANCI | c.1185A>G p.P395= | Silent (SNP) | VAF 58/164 reads (35%) | catalogued as COSV100168409; called by muse, mutect2, varscan2
- FLRT2 | c.1308C>T p.S436= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as COSV100420817; called by muse, mutect2, varscan2
- GCOM1 | c.876A>G p.L292= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as rs142159417, COSV99985200; called by muse, mutect2, varscan2
- GFPT2 | c.1494T>A p.I498= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as COSV99517959; called by muse, mutect2, varscan2
- GP1BA | c.1767A>T p.T589= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV56700042, COSV99851119; called by muse, mutect2, varscan2
- HERC1 | c.5175G>T p.V1725= | Silent (SNP) | VAF 80/228 reads (35%) | catalogued as COSV101496794; called by muse, mutect2, varscan2
- KDELR1 | c.15A>C p.R5= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99616815; called by muse, mutect2, varscan2
- LILRB5 | c.1416G>T p.L472= (on ENST00000449561 / NM_001081442.3; = p.L471= on NM_006840.5) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100300679; called by muse, mutect2, varscan2
- LOXL4 | c.1344C>T p.S448= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs780634602, COSV99584101; called by muse, mutect2, varscan2
- MAT2A | c.99T>A p.I33= | Silent (SNP) | VAF 59/188 reads (31%) | catalogued as COSV99290131; called by muse, mutect2, varscan2
- METTL27 | c.48C>T p.V16= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99936581; called by muse, mutect2, varscan2
- MTR | c.276C>T p.I92= | Silent (SNP) | VAF 56/99 reads (57%) | catalogued as rs763900581, COSV100856244; called by muse, mutect2, varscan2
- NEIL2 | c.486C>A p.S162= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs748279367, COSV99462440; called by muse, mutect2, varscan2
- PIGB | c.273T>A p.L91= | Silent (SNP) | VAF 71/210 reads (34%) | catalogued as COSV99380616; called by muse, mutect2, varscan2
- PPRC1 | c.1110T>A p.P370= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99531928; called by muse, mutect2, varscan2
- PRMT7 | c.66A>G p.E22= | Silent (SNP) | VAF 98/314 reads (31%) | catalogued as COSV100267193; called by muse, mutect2, varscan2
- SIN3B | c.1608G>A p.S536= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs773435664, COSV99931956; called by muse, mutect2
- SP8 | c.729G>A p.S243= (on ENST00000361443 / NM_198956.4; = p.S261= on NM_182700.6) | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs1179082846, COSV100815409; called by muse, mutect2
- STAB2 | c.165G>A p.P55= | Silent (SNP) | VAF 13/169 reads (8%) | catalogued as rs143894948; called by muse, mutect2
- SV2C | c.2109G>C p.L703= | Silent (SNP) | VAF 63/184 reads (34%) | catalogued as COSV100456612; called by muse, mutect2, varscan2
- TBC1D16 | c.1110A>G p.T370= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100188310; called by muse, mutect2, varscan2
- TOGARAM1 | c.297C>T p.L99= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100753222, COSV61887775; called by muse, mutect2, varscan2
- TRAK2 | c.534C>T p.V178= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV100217048; called by muse, mutect2, varscan2
- ZCCHC2 | c.1542C>T p.P514= | Silent (SNP) | VAF 69/191 reads (36%) | catalogued as rs761685230, COSV99502593; called by muse, mutect2, varscan2
- ZNF326 | c.1383A>C p.R461= | Silent (SNP) | VAF 99/270 reads (37%) | catalogued as COSV100438241; called by muse, mutect2, varscan2
- EEF1D | c.-7-2461G>A | Intron (SNP) | VAF 52/142 reads (37%) | catalogued as COSV100414990; called by muse, mutect2, varscan2
